Somatic mutation profile of tumor specimen C3N-03928-03 (aliquot CPT0223450006) from CPTAC case C3N-03928, project CPTAC-3 (Other and unspecified parts of tongue — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 60.5 years (22,113 days).
Specimen C3N-03928-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 245d63c4-a73c-40d5-8d64-d392a6ef41cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03928-71 (Blood Derived Normal), aliquot CPT0223550002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88670347-3314-4cc5-b9ee-4a842ec5f6c6

The open-access MAF lists 82 somatic variants for this specimen: 55 protein-altering or splice-affecting, 18 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 18, Nonsense Mutation 6, 3'UTR 3, RNA 3, Splice Region 3, 5'UTR 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 63/638 reads (10%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ANKS1B | c.814C>T p.Q272* | Nonsense Mutation (SNP) | VAF 6/106 reads (6%) | catalogued as COSV100247352; called by muse, mutect2
- AURKC | c.271G>A p.E91K (on ENST00000302804 / NM_001015878.2; = p.E57K on NM_003160.3) | Missense Mutation (SNP) | VAF 50/536 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs938334932, COSV57140136; called by muse, mutect2
- BTF3 | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1415192584; called by muse, mutect2
- CCN5 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs200780244, COSV51937454; called by muse, mutect2, varscan2
- CCSER1 | c.1711G>C p.E571Q | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.856); catalogued as COSV61410744, COSV61431426; called by muse, mutect2, varscan2
- CFAP70 | c.2378G>C p.R793T | Missense Mutation (SNP) | VAF 29/362 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1014959749; called by muse, mutect2
- CNTN4 | c.725C>T p.T242M | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as rs747683129, COSV61875061; called by muse, mutect2
- CSPG5 | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs944862828; called by muse, mutect2, varscan2
- HCRTR1 | c.823G>C p.E275Q | Missense Mutation (SNP) | VAF 52/460 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.02); catalogued as rs140296272; called by muse, mutect2, varscan2
- IRX4 | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs773809133; called by muse, mutect2, varscan2
- MTM1 | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 10/233 reads (4%) | catalogued as COSV60335823; called by muse, mutect2
- NEB | c.5389G>A p.D1797N | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as rs868382034; called by muse, mutect2
- NKD1 | c.128G>T p.C43F | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as rs756209640; called by muse, mutect2
- PAN3 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 27/245 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99144503; called by muse, mutect2, varscan2
- PCDH9 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.56); catalogued as COSV60587005; called by muse, mutect2
- PCDHB4 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 27/242 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.106); catalogued as rs782281410, COSV52024004; called by muse, mutect2, varscan2
- PIR | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 45/392 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as rs201144539; called by muse, mutect2, varscan2
- PRR15 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 34/281 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs1307772894; called by muse, mutect2, varscan2
- SLC39A4 | c.1301G>A p.G434E (on ENST00000301305 / NM_001374839.1; = p.G409E on NM_017767.3) | Missense Mutation (SNP) | VAF 94/1066 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs370287877; called by muse, mutect2
- SPOCK3 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.99); catalogued as rs141348000, COSV62727097; called by muse, mutect2, varscan2
- TNR | c.768C>G p.Y256* | Nonsense Mutation (SNP) | VAF 34/334 reads (10%) | catalogued as COSV99689756; called by muse, mutect2
- TRAPPC4 | c.579C>G p.I193M | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99043748; called by muse, mutect2
- USP38 | c.1048T>C p.L350= | Splice Region (SNP) | VAF 14/106 reads (13%) | catalogued as rs972663728, COSV61026784; called by muse, mutect2, varscan2
- ZMYM6 | c.3041G>A p.R1014H | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.972); catalogued as rs1266661656, COSV100593271; called by muse, mutect2, varscan2
- ALG2 | c.586C>G p.P196A | Missense Mutation (SNP) | VAF 88/403 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- ANKFN1 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.445); called by muse, mutect2
- AOC3 | c.787A>T p.K263* | Nonsense Mutation (SNP) | VAF 36/353 reads (10%) | called by muse, mutect2, varscan2
- BHLHE40 | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 18/265 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.783); called by muse, mutect2
- BRF1 | c.825G>C p.L275F | Missense Mutation (SNP) | VAF 24/520 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CD300A | c.184G>T p.V62L | Missense Mutation (SNP) | VAF 32/327 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); called by muse, mutect2
- CUX1 | c.1397T>A p.L466Q (on ENST00000437600 / NM_181500.4; = p.L468Q on NM_001913.5) | Missense Mutation (SNP) | VAF 35/288 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- DCAF8L2 | c.1870G>C p.D624H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, varscan2
- DEF6 | c.1630A>G p.N544D | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- DIS3L | c.1547C>G p.S516C (on ENST00000319212 / NM_001143688.3; = p.S433C on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- FIG4 | c.775+3A>T | Splice Region (SNP) | VAF 10/182 reads (5%) | called by muse, mutect2
- HHIPL2 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2
- IGF1R | c.341A>G p.N114S | Missense Mutation (SNP) | VAF 63/582 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- MBOAT2 | c.1135T>C p.Y379H | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MUC16 | c.17642C>A p.S5881* | Nonsense Mutation (SNP) | VAF 21/203 reads (10%) | called by muse, mutect2, varscan2
- NPHP4 | c.1039G>C p.E347Q | Missense Mutation (SNP) | VAF 9/250 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); called by muse, mutect2
- OVCH1 | c.1102C>A p.Q368K | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT tolerated (0.91); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- PCDH18 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- PCDHB11 | c.1184C>A p.S395Y | Missense Mutation (SNP) | VAF 27/285 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- PIK3R4 | c.2327C>G p.S776* | Nonsense Mutation (SNP) | VAF 11/152 reads (7%) | called by muse, mutect2
- RGPD4 | c.3859G>C p.E1287Q | Missense Mutation (SNP) | VAF 72/674 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- RYR1 | c.3274G>C p.E1092Q | Missense Mutation (SNP) | VAF 22/757 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SAGE1 | c.668T>G p.L223W | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); called by muse, mutect2
- SLC25A42 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- SYN2 | c.496C>A p.Q166K | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- SYTL2 | c.1562-6G>A | Splice Region (SNP) | VAF 10/133 reads (8%) | called by muse, mutect2
- THBS1 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- TTI1 | c.488A>G p.E163G | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZMAT1 | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF430 | c.1491C>G p.F497L | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD9 | c.813G>A p.A271= | Silent (SNP) | VAF 55/361 reads (15%) | called by muse, mutect2, varscan2
- C1QTNF4 | c.552G>A p.T184= | Silent (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- CYP26C1 | c.840G>A p.E280= | Silent (SNP) | VAF 14/157 reads (9%) | called by muse, mutect2
- ERICH3 | c.4078T>C p.L1360= | Silent (SNP) | VAF 23/257 reads (9%) | catalogued as rs781612919; called by muse, mutect2
- FAM234B | c.762C>T p.N254= | Silent (SNP) | VAF 20/280 reads (7%) | catalogued as rs759389681, COSV52193770; called by muse, mutect2
- FBXO17 | c.111C>G p.S37= | Silent (SNP) | VAF 35/384 reads (9%) | called by muse, mutect2
- GATA6 | c.235C>T p.L79= | Silent (SNP) | VAF 32/489 reads (7%) | called by muse, mutect2
- MED12 | c.3069C>T p.I1023= | Silent (SNP) | VAF 22/328 reads (7%) | catalogued as rs753751305; called by muse, mutect2
- MYBPC1 | c.877C>A p.R293= (on ENST00000550270 / NM_206820.2; = p.R318= on NM_002465.4) | Silent (SNP) | VAF 39/398 reads (10%) | catalogued as CM129132, COSV62250776; called by muse, mutect2
- OGFR | c.1165C>T p.L389= | Silent (SNP) | VAF 74/754 reads (10%) | catalogued as rs755546386; called by muse, mutect2
- OR14K1 | c.420C>T p.V140= | Silent (SNP) | VAF 18/218 reads (8%) | called by muse, mutect2
- PPM1D | c.1638G>T p.L546= | Silent (SNP) | VAF 45/384 reads (12%) | called by muse, varscan2
- PTX3 | c.258G>A p.Q86= | Silent (SNP) | VAF 41/380 reads (11%) | called by muse, mutect2, varscan2
- SEPTIN2 | c.711C>T p.F237= | Silent (SNP) | VAF 19/174 reads (11%) | catalogued as COSV104418821; called by muse, mutect2, varscan2
- TMEM47 | c.97C>T p.L33= | Silent (SNP) | VAF 35/313 reads (11%) | catalogued as rs1391570323; called by muse, mutect2, varscan2
- UPP1 | c.519G>A p.G173= | Silent (SNP) | VAF 17/544 reads (3%) | catalogued as rs1040071462, COSV57978775; called by muse, mutect2
- VCAN | c.9114T>C p.L3038= | Silent (SNP) | VAF 16/124 reads (13%) | called by muse, mutect2, varscan2
- XKR4 | c.417C>T p.R139= | Silent (SNP) | VAF 16/185 reads (9%) | catalogued as rs371460599, COSV59310500; called by muse, mutect2
- AL359195.2 | n.3446C>T | RNA (SNP) | VAF 36/360 reads (10%) | catalogued as rs1194631474; called by muse, mutect2
- CCNQP1 | n.182G>A | RNA (SNP) | VAF 53/472 reads (11%) | called by muse, mutect2, varscan2
- DAO | c.*20C>T | 3'UTR (SNP) | VAF 19/270 reads (7%) | called by muse, mutect2
- FAM182B | n.758T>A | RNA (SNP) | VAF 42/310 reads (14%) | catalogued as COSV100901287; called by muse, varscan2
- GABRG2 | c.*19G>A | 3'UTR (SNP) | VAF 23/266 reads (9%) | catalogued as COSV100729738, COSV62718074; called by muse, mutect2
- LSAMP | c.-34G>A | 5'UTR (SNP) | VAF 8/56 reads (14%) | catalogued as rs914116658; called by muse, mutect2, varscan2
- NXPH3 | c.-1G>C | 5'UTR (SNP) | VAF 15/486 reads (3%) | called by muse, mutect2
- PATZ1 | chr22:31347014 G>T | 5'Flank (SNP) | VAF 12/121 reads (10%) | called by muse, mutect2
- SMG5 | c.*826G>C | 3'UTR (SNP) | VAF 11/323 reads (3%) | called by muse, mutect2
